Somatic mutation profile of tumor specimen TCGA-3L-AA1B-01A (aliquot TCGA-3L-AA1B-01A-11D-A36X-10) from TCGA case TCGA-3L-AA1B, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage I; Age at diagnosis: 61.3 years (22,379 days).
Specimen TCGA-3L-AA1B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8cf00001-b294-409a-b78f-ea54ffe18a0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3L-AA1B-10A (Blood Derived Normal), aliquot TCGA-3L-AA1B-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/144983c0-174b-45c1-90c3-327e217ce685

The open-access MAF lists 145 somatic variants for this specimen: 101 protein-altering or splice-affecting, 40 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 40, Nonsense Mutation 6, Intron 2, 3'Flank 1, 5'Flank 1, Splice Region 1, Frame Shift Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 38/88 reads (43%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 11/136 reads (8%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- BRAF | c.1909C>G p.L637V (on ENST00000288602 / NM_001374244.1; = p.L597V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs121913369, CM092080, COSV56128388, COSV56136773; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 29/124 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 134/457 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA6 | c.3196G>A p.V1066I | Missense Mutation (SNP) | VAF 43/299 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs766759180, COSV52641225; called by muse, mutect2, varscan2
- ACSBG1 | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.892); catalogued as rs370057969; called by muse, mutect2, varscan2
- AKAP6 | c.3163A>G p.K1055E | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.551); catalogued as COSV99801363; called by muse, varscan2
- ARHGAP11A | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 42/328 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755147180, COSV100853260; called by muse, mutect2, varscan2
- ARPP21 | c.1207G>T p.G403W | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51793062, COSV99492221; called by muse, mutect2, varscan2
- ATRX | c.5698-1G>C p.X1900_splice | Splice Site (SNP) | VAF 20/496 reads (4%) | catalogued as COSV100970786, COSV64881768; called by muse, mutect2
- C10orf90 | c.439G>A p.V147M | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs138339872, COSV52956297; called by muse, mutect2, varscan2
- C2CD6 | c.178A>G p.T60A | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99633227; called by muse, mutect2, varscan2
- CABP4 | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.363); catalogued as COSV100351543; called by muse, mutect2
- CCNL2 | c.142A>T p.T48S | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as COSV100784983; called by muse, mutect2, varscan2
- CD200R1L | c.727T>C p.Y243H | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as COSV101236595; called by muse, mutect2, varscan2
- CEP128 | c.1150G>T p.V384L | Missense Mutation (SNP) | VAF 52/257 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99383339; called by muse, mutect2, varscan2
- CEP97 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs145086802; called by muse, mutect2, varscan2
- CLEC3A | c.577C>T p.R193C (on ENST00000651443; = p.R184C on NM_005752.6) | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs761179747, COSV100222086; called by muse, mutect2, varscan2
- COL16A1 | c.986C>T p.T329I | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as rs1330350490, COSV99594612; called by muse, mutect2, varscan2
- COL4A5 | c.4228C>T p.R1410C | Missense Mutation (SNP) | VAF 74/303 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as rs104886270, CM960393, COSV60377043; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COLEC11 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52591302, COSV99363321; called by muse, mutect2, varscan2
- CRBN | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV99214202; called by muse, mutect2, varscan2
- CSMD2 | c.6098G>A p.R2033H | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs148199011; called by muse, mutect2, varscan2
- DIRAS1 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1350213752, COSV60214887; called by muse, mutect2, varscan2
- DISP3 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99608818; called by muse, mutect2, varscan2
- DOCK3 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as rs756421617, COSV56539986; called by muse, mutect2, varscan2
- DYNC2H1 | c.10844C>T p.P3615L | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1468117934, COSV100518727, COSV100519674; called by muse, mutect2, varscan2
- EBF1 | c.1501G>A p.G501S | Missense Mutation (SNP) | VAF 64/139 reads (46%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.009); catalogued as rs181351521; called by muse, mutect2, varscan2
- ELF4 | c.1015G>T p.A339S | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV100257396; called by muse, mutect2
- EPHA4 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 90/342 reads (26%) | catalogued as COSV56039217; called by muse, mutect2, varscan2
- EPPK1 | c.6652C>G p.R2218G | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101599862; called by muse, mutect2, varscan2
- EVC | c.1939C>T p.R647W | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770276380, COSV53835082; called by muse, mutect2, varscan2
- FAM126B | c.1264C>G p.L422V | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV53774643; called by muse, mutect2, varscan2
- FIGN | c.1410C>A p.D470E | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.068); catalogued as COSV100292454; called by muse, mutect2, varscan2
- FOXD2 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV100599252; called by muse, mutect2, varscan2
- GAPT | c.173C>G p.T58S | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100576312; called by muse, mutect2, varscan2
- GDPD2 | c.595G>C p.V199L | Missense Mutation (SNP) | VAF 13/265 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV100978567; called by muse, mutect2
- GPR83 | c.1040G>T p.W347L | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV54720321; called by muse, mutect2, varscan2
- GRM2 | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.863); catalogued as rs764654881, COSV56584592, COSV56584954; called by muse, mutect2, varscan2
- H2BW1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 71/199 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs367978385, COSV99475079; called by muse, mutect2, varscan2
- HMGCR | c.109T>C p.F37L | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV55317675; called by muse, mutect2, varscan2
- HRNR | c.676G>T p.G226C | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.615); catalogued as COSV100913540, COSV64263809; called by muse, mutect2, varscan2
- INSYN1 | c.518G>A p.S173N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV101138787; called by muse, mutect2, varscan2
- IQCA1 | c.9C>T p.N3= | Splice Region (SNP) | VAF 19/154 reads (12%) | catalogued as COSV54510368; called by muse, mutect2, varscan2
- KBTBD8 | c.779C>A p.A260D | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as COSV99805695; called by muse, mutect2, varscan2
- KCNG2 | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs770849909, COSV60269605; called by muse, mutect2, varscan2
- KIAA1109 | c.7154A>G p.N2385S | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.523); catalogued as rs768423492, COSV99164938; called by muse, mutect2, varscan2
- KMT2C | c.2516G>C p.R839T | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1401497698, COSV100072529; called by muse, mutect2, varscan2
- LRRK1 | c.4218G>T p.K1406N | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99440454; called by muse, mutect2, varscan2
- MAP3K4 | c.4096G>A p.G1366R | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815616, COSV62329900; called by muse, mutect2
- MATN4 | c.1403C>T p.A468V (on ENST00000372754; = p.A427V on NM_003833.4) | Missense Mutation (SNP) | VAF 9/91 reads (10%) | PolyPhen probably damaging (0.999); catalogued as rs144151421; called by muse, mutect2, varscan2
- MTREX | c.3121T>G p.Y1041D | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99301739; called by muse, mutect2, varscan2
- MYO5A | c.1604G>C p.C535S | Missense Mutation (SNP) | VAF 71/232 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100697726; called by muse, mutect2, varscan2
- NALCN | c.400G>T p.D134Y | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT tolerated (1); PolyPhen possibly damaging (0.87); catalogued as COSV51960026, COSV99214143; called by muse, mutect2, varscan2
- NAP1L2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 85/270 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.959); catalogued as rs17852391, COSV65173070; called by muse, mutect2, varscan2
- NUBP1 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV51595272; called by muse, mutect2
- OOEP | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs1179160604, COSV64859331; called by muse, mutect2, varscan2
- PABPC3 | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs757885062, COSV55799889; called by muse, mutect2, varscan2
- PCDH12 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as rs550140086, COSV51524306; called by muse, mutect2, varscan2
- PCDHA3 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV63539069; called by muse, mutect2
- PLXND1 | c.2216G>A p.R739Q | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as rs138740853; called by muse, mutect2, varscan2
- PPP2R1A | c.412G>A p.G138S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV100436301; called by muse, mutect2, varscan2
- PREB | c.505C>A p.L169I | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as COSV53207892; called by muse, mutect2
- PRKCQ | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 63/234 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1206058542, COSV54105384, COSV99577051; called by muse, mutect2, varscan2
- PRPF8 | c.5495G>A p.R1832H | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59264706; called by muse, mutect2, varscan2
- PTPN14 | c.1798C>T p.R600W | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775147296, COSV65290229; called by muse, mutect2, varscan2
- PTPRC | c.207C>A p.F69L | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV61408882; called by muse, mutect2, varscan2
- R3HDM1 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 100/389 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs755222892, COSV51531288; called by muse, mutect2, varscan2
- RADIL | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs756246829, COSV68203067; called by muse, mutect2, varscan2
- RDM1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs760143593; called by muse, mutect2, varscan2
- RGS9 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.424); catalogued as rs1298439298, COSV52226664; called by muse, mutect2, varscan2
- RHOBTB3 | c.1325G>A p.C442Y | Missense Mutation (SNP) | VAF 90/219 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV101183208, COSV66103422; called by muse, mutect2, varscan2
- SAP130 | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52094617; called by muse, mutect2, varscan2
- SETDB2 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs758868733, COSV99320807; called by muse, mutect2, varscan2
- SLC25A37 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs746602617, COSV51564178; called by muse, mutect2, varscan2
- SLC32A1 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.155); catalogued as COSV99462315; called by muse, mutect2, varscan2
- SLC52A2 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV100095797; called by muse, mutect2, varscan2
- SNRPN | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs775190561, COSV57594364, COSV57599888; called by muse, mutect2, varscan2
- SPATA31E1 | c.1657C>A p.Q553K | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV100350554, COSV57795259; called by muse, mutect2, varscan2
- SPIRE2 | c.1738C>T p.P580S | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV65557251; called by muse, mutect2, varscan2
- SPON1 | c.230G>A p.S77N | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs1554907695, COSV100116004; called by muse, mutect2
- SRGAP3 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs1469070230, COSV100841001; called by muse, mutect2, varscan2
- STOX2 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1225723250, COSV57852746; called by muse, mutect2, varscan2
- SV2C | c.408G>T p.Q136H | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.05); catalogued as COSV100456300; called by muse, mutect2, varscan2
- TENM2 | c.6112G>A p.V2038I (on ENST00000518659 / NM_001122679.2; = p.V1799I on NM_001080428.3) | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.172); catalogued as rs374139941; called by muse, mutect2, varscan2
- TESPA1 | c.1384C>A p.Q462K (on ENST00000316577 / NM_001098815.3; = p.Q324K on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/225 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.092); catalogued as rs187244716, COSV100345290; called by muse, mutect2, varscan2
- TNR | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.453); catalogued as rs1245465561, COSV54887052; called by muse, mutect2, varscan2
- TRIM55 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs150362738; called by muse, mutect2, varscan2
- TTLL5 | c.1432C>T p.R478W | Missense Mutation (SNP) | VAF 103/525 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778757743, COSV54046888; called by muse, mutect2, varscan2
- USP34 | c.4348C>A p.P1450T | Missense Mutation (SNP) | VAF 70/353 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); catalogued as COSV101277063; called by muse, mutect2, varscan2
- YBEY | c.5G>T p.S2I | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99387037; called by muse, mutect2
- ZDHHC15 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 98/410 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs1407325291, COSV64902875; called by muse, mutect2, varscan2
- ZMYM5 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 80/258 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.883); catalogued as rs754542115, COSV61987078; called by muse, mutect2, varscan2
- ZNF483 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 18/98 reads (18%) | catalogued as COSV100492924; called by muse, mutect2, varscan2
- ZNF536 | c.3004G>A p.G1002S | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as rs752209246, COSV62829411; called by muse, mutect2, varscan2
- ZNF662 | c.826T>C p.F276L | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs781421409, COSV100066391; called by muse, mutect2, varscan2
- ZXDA | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.793); catalogued as COSV62388324; called by muse, mutect2, varscan2
- MAGEE1 | c.2142dup p.E715* | Frame Shift Ins (INS) | VAF 52/194 reads (27%) | called by mutect2, varscan2
- MLLT6 | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- NOX5 | c.1407del p.H470Tfs*10 | Frame Shift Del (DEL) | VAF 31/132 reads (23%) | called by mutect2, pindel, varscan2
- ABCB7 | c.654C>A p.A218= (on ENST00000373394 / NM_001271696.3; = p.A219= on NM_004299.6) | Silent (SNP) | VAF 93/337 reads (28%) | catalogued as COSV99504428; called by muse, mutect2, varscan2
- ABCC12 | c.2862C>T p.V954= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs550873538, COSV60912265; called by muse, mutect2, varscan2
- ABLIM3 | c.1374G>A p.K458= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV100448497; called by muse, mutect2, varscan2
- ACTC1 | c.42C>T p.N14= | Silent (SNP) | VAF 46/147 reads (31%) | catalogued as rs1257278537, COSV51762009; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAMTS17 | c.2193C>A p.P731= | Silent (SNP) | VAF 10/117 reads (9%) | catalogued as rs1477119001, COSV51473484; called by muse, mutect2
- ADAMTS7 | c.156C>T p.D52= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as rs986714527, COSV66309070; called by muse, varscan2
- AFDN | c.3525C>T p.N1175= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs367706314; called by muse, mutect2, varscan2
- AMPD2 | c.2184C>T p.I728= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs367822022; ClinVar: likely benign; called by muse, varscan2
- ATP2A1 | c.2701C>T p.L901= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as rs1179309357, COSV100707074, COSV62869796; called by muse, mutect2, varscan2
- CARD10 | c.1167G>A p.E389= | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as COSV52660073; called by muse, mutect2, varscan2
- CARD11 | c.3174C>T p.I1058= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs369919588, COSV67800792; ClinVar: likely benign; called by muse, mutect2, varscan2
- CHST13 | c.165C>G p.L55= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV60041944, COSV60043060; called by muse, mutect2, varscan2
- CMBL | c.141C>T p.V47= | Silent (SNP) | VAF 38/94 reads (40%) | catalogued as COSV56984588, COSV99687063; called by muse, mutect2, varscan2
- CSMD2 | c.3402G>A p.K1134= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as rs761628107, COSV99591036; called by muse, mutect2, varscan2
- DMBT1 | c.7335T>C p.Y2445= (on ENST00000338354 / NM_001377530.1; = p.Y1688= on NM_004406.3) | Silent (SNP) | VAF 22/133 reads (17%) | catalogued as rs781425662, COSV57557364; called by muse, mutect2, varscan2
- DMPK | c.909C>T p.D303= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs200058479, COSV99353229; called by muse, mutect2, varscan2
- DOCK4 | c.5340G>A p.S1780= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs139961687; called by muse, mutect2, varscan2
- F10 | c.894C>T p.G298= | Silent (SNP) | VAF 56/166 reads (34%) | catalogued as rs778741024, COSV65020771; called by muse, mutect2, varscan2
- FREM2 | c.675C>T p.G225= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV54831126; called by muse, mutect2, varscan2
- GREB1 | c.2688G>A p.A896= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as rs779389270, COSV52196328; called by muse, mutect2, varscan2
- ITIH6 | c.648C>T p.I216= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs749178155, COSV99513402; called by muse, mutect2, varscan2
- ITPR3 | c.4119C>T p.A1373= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as rs758747831, COSV100967445; called by muse, mutect2
- MAGEB4 | c.171C>A p.G57= | Silent (SNP) | VAF 84/260 reads (32%) | catalogued as COSV100854710; called by muse, mutect2, varscan2
- MAP1B | c.1668C>T p.S556= | Silent (SNP) | VAF 23/142 reads (16%) | catalogued as rs767457558, COSV99701550, COSV99702465; called by muse, mutect2, varscan2
- MAP3K12 | c.996C>T p.P332= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV99913308; called by muse, mutect2, varscan2
- MBD5 | c.993A>G p.K331= | Silent (SNP) | VAF 18/175 reads (10%) | catalogued as COSV101290108; called by muse, mutect2, varscan2
- MBP | c.525C>T p.I175= (on ENST00000355994 / NM_001025101.2; = p.I42= on NM_002385.3) | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as rs760796623, COSV62830252; called by muse, mutect2, varscan2
- MMRN1 | c.1977C>G p.L659= | Silent (SNP) | VAF 48/106 reads (45%) | catalogued as COSV99307211; called by muse, varscan2
- NLRP1 | c.2268C>T p.F756= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as COSV99333451; called by muse, mutect2, varscan2
- PIGO | c.2361C>T p.P787= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs144233446, COSV99956719; called by muse, mutect2, varscan2
- PRAMEF20 | c.198G>T p.L66= | Silent (SNP) | VAF 68/569 reads (12%) | called by muse, mutect2, varscan2
- RPS4X | c.379A>C p.R127= | Silent (SNP) | VAF 80/326 reads (25%) | catalogued as COSV100289082; called by muse, mutect2, varscan2
- RYR1 | c.5275C>A p.R1759= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV100615910, COSV62098979; called by muse, mutect2, varscan2
- SH3TC1 | c.2070G>A p.R690= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV99794921; called by muse, mutect2, varscan2
- SOX8 | c.1074C>T p.Y358= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs755524354, COSV99559252; called by muse, mutect2, varscan2
- THSD7A | c.300G>A p.K100= | Silent (SNP) | VAF 35/173 reads (20%) | catalogued as COSV101448743; called by muse, mutect2, varscan2
- TMEM164 | c.744C>T p.Y248= (on ENST00000372068 / NM_032227.4; = p.Y99= on NM_017698.2) | Silent (SNP) | VAF 34/175 reads (19%) | catalogued as COSV99911761; called by muse, mutect2, varscan2
- TNFRSF1A | c.1191C>T p.R397= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99164299; called by muse, mutect2, varscan2
- ZNF831 | c.1695C>T p.A565= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV100926061; called by muse, mutect2, varscan2
- ZNF835 | c.906C>T p.G302= | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as COSV101606292; called by muse, mutect2, varscan2
- NOL9 | chr1:6519500 G>A | 3'Flank (SNP) | VAF 21/66 reads (32%) | catalogued as rs1283685386, COSV100891469; called by muse, mutect2, varscan2
- OBSCN | c.11660-1006C>T | Intron (SNP) | VAF 25/66 reads (38%) | catalogued as rs555353918, COSV99479344; called by muse, mutect2, varscan2
- PDPN | chr1:13583821 G>A | 5'Flank (SNP) | VAF 22/79 reads (28%) | catalogued as rs771483531, COSV99611505, COSV99611510; called by muse, mutect2, varscan2
- PTGER3 | c.1077+39G>T | Intron (SNP) | VAF 41/106 reads (39%) | catalogued as COSV100138973; called by muse, mutect2, varscan2
